Somatic mutation profile of tumor specimen TCGA-A5-A0G9-01A (aliquot TCGA-A5-A0G9-01A-11W-A062-09) from TCGA case TCGA-A5-A0G9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 79.7 years (29,122 days).
Specimen TCGA-A5-A0G9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce037085-9b6a-4709-9184-6b164c070a49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0G9-10A (Blood Derived Normal), aliquot TCGA-A5-A0G9-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fce290ac-2470-4dff-add7-2f85c2492293

The open-access MAF lists 483 somatic variants for this specimen: 391 protein-altering or splice-affecting, 80 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 289, Silent 80, Frame Shift Del 60, Frame Shift Ins 12, Nonsense Mutation 12, Intron 9, Splice Site 7, Splice Region 4, In Frame Del 3, Nonstop Mutation 3, 3'Flank 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3309dup p.D1104Rfs*2 | Frame Shift Ins (INS) | VAF 78/205 reads (38%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- ASPH | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374385878, CM144721; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYNC1H1 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 5/121 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs863223361, CM163684, COSV64138416; ClinVar: pathogenic; called by muse, mutect2
- HNF1B | c.1561del p.Q521Sfs*70 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ITGB4 | c.600del p.F201Sfs*9 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs752657203, COSV52322249, COSV52323301; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KDM6A | c.2832+1G>A p.X944_splice | Splice Site (SNP) | VAF 15/221 reads (7%) | catalogued as rs1135401809, COSV65037460, COSV65040731; ClinVar: pathogenic; called by muse, mutect2
- MKRN3 | c.482del p.P161Rfs*10 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 20/121 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- PTEN | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 246/287 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USP9X | c.7440dup p.A2481Sfs*17 | Frame Shift Ins (INS) | VAF 40/140 reads (29%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, varscan2
- A2ML1 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 22/800 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs932293502, COSV55292927; called by muse, mutect2
- ABCA6 | c.4617-1G>T p.X1539_splice | Splice Site (SNP) | VAF 40/410 reads (10%) | catalogued as COSV52640457, COSV52642482; called by muse, mutect2, varscan2
- AC004593.2 | c.1125A>T p.E375D | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56095183; called by muse, mutect2
- ACAN | c.6354G>T p.E2118D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV61363059; called by muse, mutect2, varscan2
- ACAP2 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58753078; called by muse, mutect2
- ACE | c.1352T>C p.I451T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1158360384, COSV52008611; called by muse, mutect2, varscan2
- ADAMTS4 | c.1613del p.G538Vfs*43 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | catalogued as rs1477847069; called by mutect2, pindel, varscan2
- ADAMTS9 | c.5424C>A p.S1808R | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV55784023; called by muse, mutect2
- ADD3 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.948); catalogued as COSV53323384, COSV53324860; called by muse, mutect2, varscan2
- ADIG | c.58T>C p.W20R | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV53439671; called by muse, mutect2, varscan2
- AKNA | c.3969dup p.G1324Rfs*144 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | catalogued as rs770120077; called by mutect2, pindel, varscan2
- ALG5 | c.440T>A p.I147N | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV53505985; called by muse, mutect2
- AMOTL1 | c.161T>C p.L54S | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100133863, COSV54416637; called by muse, mutect2
- ANAPC4 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs766016624, COSV59544787; called by muse, mutect2, varscan2
- ANKLE2 | c.1743G>T p.W581C | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61709743, COSV61710107; called by muse, mutect2
- ANKRD12 | c.2804del p.N935Ifs*24 | Frame Shift Del (DEL) | VAF 54/155 reads (35%) | catalogued as rs868780344; called by mutect2, varscan2
- ANKRD52 | c.2267C>T p.T756M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771081273, COSV57283454; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs999461756; called by mutect2, pindel
- ARHGAP27 | c.1328A>C p.Q443P (on ENST00000428638 / NM_001282290.1; = p.Q102P on NM_199282.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs754414421, COSV65358019; called by muse, mutect2, varscan2
- ARHGEF12 | c.25A>T p.T9S | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.978); catalogued as COSV63105617; called by muse, mutect2
- ARHGEF15 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.86); catalogued as rs750554328, COSV62725606; called by muse, mutect2, varscan2
- ARID1B | c.4960A>T p.T1654S | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.1); catalogued as COSV51667504; called by muse, mutect2
- ARID5B | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 58/123 reads (47%) | catalogued as COSV54422989; called by muse, mutect2, varscan2
- ARMC4 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs758192226, COSV59466081; called by muse, mutect2, varscan2
- ARMC4 | c.818G>C p.G273A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV53466103; called by muse, mutect2, varscan2
- ATP1A3 | c.464C>T p.A155V (on ENST00000545399 / NM_001256214.2; = p.A142V on NM_152296.5) | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV57488631; called by muse, mutect2
- ATP1B2 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV51515891; called by muse, mutect2
- ATP2B3 | c.3386T>C p.L1129P | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV54851701; called by muse, mutect2
- ATP6V0A1 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV52874712; called by muse, mutect2
- ATP6V1H | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100778883, COSV62218917; called by muse, mutect2, varscan2
- BAZ2B | c.4205G>C p.S1402T | Missense Mutation (SNP) | VAF 91/232 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV58603717; called by muse, mutect2, varscan2
- BIVM | c.1494T>A p.D498E | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); catalogued as COSV57280458; called by muse, mutect2
- BMP1 | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV59244378; called by muse, mutect2, varscan2
- BMP2K | c.1090A>T p.T364S | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV58596315; called by muse, mutect2
- BNC2 | c.2951G>A p.S984N | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV66168467; called by muse, mutect2
- BRMS1L | c.444C>T p.S148= | Splice Region (SNP) | VAF 18/140 reads (13%) | catalogued as rs1267795187, COSV53763671; called by muse, mutect2, varscan2
- BSN | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs572736678, COSV56523448; called by muse, mutect2
- BTBD3 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV54779941, COSV54782447; called by muse, mutect2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- CACYBP | c.463A>G p.R155G | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV62881292; called by muse, mutect2, varscan2
- CAPZA3 | c.562A>G p.R188G | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV56854563; called by muse, mutect2
- CCDC136 | c.3401C>A p.P1134H | Missense Mutation (SNP) | VAF 36/753 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257075336, COSV52801094; called by muse, mutect2
- CCDC171 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs1255418106, COSV52644552; called by muse, mutect2, varscan2
- CCDC38 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 6/175 reads (3%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV60183606; called by muse, mutect2
- CCDC7 | c.87A>T p.L29F | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.997); catalogued as COSV53231082; called by muse, mutect2
- CCDC93 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.705); catalogued as COSV60122135; called by muse, mutect2, varscan2
- CCDC9B | c.590del p.R197Lfs*2 | Frame Shift Del (DEL) | VAF 4/49 reads (8%) | catalogued as COSV66874938, COSV66875705; called by mutect2, pindel
- CD93 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); catalogued as COSV55667064, COSV99849516; called by muse, mutect2
- CD99L2 | c.776C>A p.P259Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV60935576, COSV60936962; called by muse, mutect2, varscan2
- CDC73 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV66465964, COSV66470998; called by muse, mutect2, varscan2
- CDH11 | c.2093C>A p.P698H | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV51760859; called by muse, mutect2, varscan2
- CDH12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 96/243 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs147080212; called by muse, mutect2, varscan2
- CDH7 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs751741132, COSV59883604; called by muse, mutect2, varscan2
- CENPB | c.1312del p.E438Kfs*43 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs748211874; called by mutect2, pindel
- CFAP54 | c.5269G>T p.V1757L | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.14); catalogued as COSV61572884; called by muse, mutect2, varscan2
- CLDN20 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 95/245 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65697556; called by muse, mutect2, varscan2
- CLEC12A | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1283660732, COSV58561657; called by muse, mutect2
- CLN5 | c.*8-2A>C | Splice Site (SNP) | VAF 6/88 reads (7%) | catalogued as COSV62918914; called by muse, mutect2
- CNBP | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69654703; called by muse, mutect2
- CNOT10 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.525); catalogued as COSV59392810; called by muse, mutect2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 11/67 reads (16%) | catalogued as rs760493024; called by mutect2, varscan2
- COL28A1 | c.2691del p.V898Wfs*18 | Frame Shift Del (DEL) | VAF 27/127 reads (21%) | catalogued as rs766010947; called by mutect2, pindel, varscan2
- CPNE3 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV52207504; called by muse, mutect2
- CPVL | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV55304316; called by muse, mutect2
- CREBBP | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.801); catalogued as rs750216784, COSV52114957, COSV52122825; called by muse, mutect2, varscan2
- CSHL1 | c.309C>T p.N103= (on ENST00000309894 / NM_022581.3; = p.N9= on NM_001318.4) | Splice Region (SNP) | VAF 8/56 reads (14%) | catalogued as rs549363202, COSV51988795, COSV51990274; called by muse, mutect2, varscan2
- CTNND1 | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV62382532, COSV62384301, COSV62386520; called by muse, mutect2
- CUBN | c.10362+2T>C p.X3454_splice | Splice Site (SNP) | VAF 33/262 reads (13%) | catalogued as COSV64719190; called by muse, mutect2, varscan2
- CUBN | c.6772C>T p.R2258C | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.677); catalogued as rs774125861, COSV100912096; called by muse, mutect2
- CUBN | c.2529G>T p.R843S | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.167); catalogued as rs1219055456, COSV64719194, COSV64729032; called by muse, mutect2
- CYLD | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV61095606; called by muse, mutect2, varscan2
- CYP2C8 | c.1076G>A p.S359N | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV64877734; called by muse, mutect2
- DAAM1 | c.2359G>A p.V787M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.688); catalogued as COSV62837380; called by muse, mutect2, varscan2
- DAB1 | c.439-1G>T p.X147_splice | Splice Site (SNP) | VAF 35/98 reads (36%) | catalogued as COSV59730392; called by muse, mutect2, varscan2
- DAGLA | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as rs755679985, COSV57197335; called by muse, mutect2
- DBNDD2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs541954493, COSV100619599; called by muse, mutect2
- DCAF12L2 | c.539C>G p.P180R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63581327, COSV63582472; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX49 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs771624240, COSV53231069; called by mutect2, varscan2
- DGKK | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868993225, COSV65708080; called by muse, mutect2
- DHX38 | c.2805C>A p.N935K | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs754495430, COSV51698849; called by muse, mutect2
- DLK1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV57992184, COSV57992917; called by muse, mutect2, varscan2
- DNAJC27 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as COSV53095583; called by muse, mutect2
- DNER | c.1097A>T p.D366V | Missense Mutation (SNP) | VAF 23/497 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59169308; called by muse, mutect2
- DOCK11 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 21/518 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1282547776, COSV52241669; called by muse, mutect2
- DOCK4 | c.4718A>G p.H1573R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70239082; called by muse, mutect2
- DOP1A | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749497283, COSV52710679; called by muse, mutect2
- DYNC1H1 | c.11317C>A p.L3773M | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64138429; called by muse, mutect2
- EEA1 | c.306A>C p.E102D | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV59287006; called by muse, mutect2
- EFCAB13 | c.1958T>A p.V653E | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58949758; called by muse, mutect2, varscan2
- EIF1AX | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63309369; called by muse, mutect2, varscan2
- EIF5B | c.3007G>T p.V1003L | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV56814198; called by muse, mutect2
- ENDOD1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV53589974; called by muse, mutect2, varscan2
- ENOX2 | c.163G>A p.A55T (on ENST00000338144 / NM_001382520.1; = p.A26T on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57653372; called by muse, mutect2, varscan2
- EPHX2 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs1347152892, COSV66844611; called by muse, mutect2, varscan2
- EPRS1 | c.4099C>T p.L1367F | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV65099864; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 66/114 reads (58%) | catalogued as rs775950025; called by mutect2, varscan2
- FANCM | c.4005dup p.V1336Sfs*8 | Frame Shift Ins (INS) | VAF 32/120 reads (27%) | catalogued as rs746983128; called by mutect2, varscan2
- FAT3 | c.10043C>T p.A3348V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as rs376234071, COSV53112247; called by muse, mutect2, varscan2
- FCRL5 | c.64A>G p.R22G | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1240676505, COSV62516202; called by muse, mutect2, varscan2
- FRA10AC1 | c.694del p.R232Efs*96 | Frame Shift Del (DEL) | VAF 32/124 reads (26%) | catalogued as rs775948504; called by mutect2, varscan2
- FRMPD2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV59719468; called by muse, mutect2, varscan2
- FUNDC2 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 132/431 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65671201; called by muse, mutect2, varscan2
- FUS | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as rs768259829, COSV54218037; called by muse, mutect2
- FXR1 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV59763983; called by muse, mutect2, varscan2
- GALNT13 | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV67225939; called by muse, mutect2, varscan2
- GAPT | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 11/241 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs1284370542, COSV59247072; called by muse, mutect2
- GAREM1 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 7/224 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1380421176, COSV52511531; called by muse, mutect2
- GARRE1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs1330864622, COSV55100811; called by muse, mutect2, varscan2
- GBP1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs778464169, COSV65083826; called by muse, mutect2, varscan2
- GIN1 | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1554195130, COSV67537089; called by muse, mutect2, varscan2
- GLB1L3 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV68392995; called by muse, mutect2
- GPHN | c.1336C>T p.R446* (on ENST00000315266 / NM_001377519.1; = p.R479* on NM_020806.5) | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | catalogued as rs778591008, COSV59472614; called by muse, mutect2, varscan2
- GPR107 | c.1502T>A p.I501N (on ENST00000372406 / NM_001136557.2; = p.I453N on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61280525; called by muse, mutect2
- GPR142 | c.191del p.G64Efs*7 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as COSV100170723; called by mutect2, pindel, varscan2
- GREB1 | c.2120A>G p.Y707C | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV52189950; called by muse, mutect2
- GRIA3 | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as COSV52067415; called by muse, mutect2, varscan2
- GTF3C1 | c.3530T>G p.I1177S | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV62242269; called by muse, mutect2, varscan2
- GTF3C2 | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 189/513 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as COSV53127282; called by muse, mutect2, varscan2
- H1-1 | c.535A>G p.K179E | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV55119809; called by muse, mutect2, varscan2
- HCN4 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420807618, COSV56082015; called by muse, mutect2, varscan2
- HEATR1 | c.6315A>T p.E2105D | Missense Mutation (SNP) | VAF 20/706 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV59381963; called by muse, mutect2
- HHATL | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60042180; called by muse, mutect2, varscan2
- HHIPL1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58091543; called by muse, varscan2
- HHIPL2 | c.505T>C p.C169R | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1210117647, COSV58565919; called by muse, mutect2
- HIRA | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs761210709, COSV54276348; called by muse, mutect2, varscan2
- HNF4G | c.1077G>A p.M359I (on ENST00000354370 / NM_001330561.2; = p.M406I on NM_004133.5) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV62969977; called by muse, mutect2, varscan2
- HNRNPR | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56422467; called by muse, mutect2
- HSD17B3 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV64557485; called by muse, mutect2, varscan2
- IGHV5-51 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs782566695; called by muse, mutect2
- IGKV4-1 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as rs778305195; called by muse, mutect2
- IGSF22 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60035619; called by muse, mutect2, varscan2
- INSRR | c.1163T>C p.F388S | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV63874778; called by muse, mutect2, varscan2
- INSYN1 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV65837515; called by muse, mutect2
- INTS6L | c.2045T>C p.M682T | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs782304320, COSV66084855; called by muse, mutect2, varscan2
- IP6K1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as rs1000417584, COSV58664108; called by muse, mutect2, varscan2
- ISCA1 | c.242-1G>A p.X81_splice | Splice Site (SNP) | VAF 65/204 reads (32%) | catalogued as rs554783681, COSV58181765; called by muse, mutect2, varscan2
- ITPR1 | c.4178C>T p.T1393I (on ENST00000354582; = p.T1378I on NM_002222.7) | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56987681; called by muse, mutect2
- ITPRIPL1 | c.1330C>T p.L444F (on ENST00000439118 / NM_001008949.3; = p.L452F on NM_178495.6) | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63153873; called by muse, mutect2
- JAG1 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV54758604; called by muse, mutect2, varscan2
- JAK1 | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV61092928; called by muse, mutect2
- JCAD | c.759A>C p.R253S | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV64760313; called by muse, mutect2
- KBTBD3 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs753092290, COSV73241490; called by muse, mutect2, varscan2
- KCNG1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as rs1187419187, COSV65368174; called by muse, mutect2, varscan2
- KCNN3 | c.2080G>A p.D694N (on ENST00000618040 / NM_001204087.1; = p.D679N on NM_002249.6) | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as COSV55219727; called by muse, mutect2, varscan2
- KDM4A | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.054); catalogued as rs1246741399, COSV64959662; called by muse, mutect2
- KDR | c.2284A>T p.N762Y | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV55768264; called by muse, mutect2, varscan2
- KIAA0100 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1202780206, COSV66490667; called by muse, mutect2, varscan2
- KIF20B | c.4165G>A p.V1389I (on ENST00000371728 / NM_001284259.2; = p.V1349I on NM_016195.4) | Missense Mutation (SNP) | VAF 14/482 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV53309684; called by muse, mutect2
- KLHL31 | c.884A>G p.H295R | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63881974; called by muse, mutect2, varscan2
- KMT5B | c.83A>T p.N28I | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV58567328; called by muse, mutect2
- KRT26 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs185320223, COSV56971709; called by muse, mutect2, varscan2
- KRTAP20-2 | c.196T>C p.*66Rext*46 | Nonstop Mutation (SNP) | VAF 13/206 reads (6%) | catalogued as COSV100424538; called by muse, mutect2
- KSR2 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1565883551, COSV56671270; called by muse, mutect2, varscan2
- LATS1 | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53593340; called by muse, mutect2, varscan2
- LIN52 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1227181611, COSV73465917; called by muse, mutect2, varscan2
- LNX1 | c.1690G>A p.V564I (on ENST00000263925 / NM_001126328.3; = p.V468I on NM_032622.2) | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55782140; called by muse, mutect2, varscan2
- LPAR4 | c.91T>C p.C31R | Missense Mutation (SNP) | VAF 167/359 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV70912862; called by muse, mutect2, varscan2
- LPIN2 | c.194T>A p.I65N | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55240893; called by muse, mutect2
- LRRC4 | c.314A>G p.Q105R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV50814986, COSV99974926; called by muse, mutect2, varscan2
- LRRC55 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs764379210, COSV73006659, COSV73006680; called by muse, mutect2, varscan2
- LRRC7 | c.2683G>A p.A895T (on ENST00000651989 / NM_001370785.2; = p.A862T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1455950577, COSV50456565, COSV50534238; called by muse, mutect2, varscan2
- LRRC8A | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as rs766650861, COSV52186934; called by muse, mutect2, varscan2
- LRRC8B | c.714T>A p.F238L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58375719; called by muse, mutect2
- LRRK2 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368291361; called by muse, mutect2, varscan2
- LYSMD1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 20/550 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV64420234; called by muse, mutect2
- LYST | c.3140C>A p.P1047H | Missense Mutation (SNP) | VAF 87/533 reads (16%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.046); catalogued as COSV67707434; called by muse, mutect2, varscan2
- LYST | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 75/429 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); catalogued as rs752192687, COSV67705371; called by muse, mutect2, varscan2
- MACF1 | c.14341G>T p.G4781C (on ENST00000372915; = p.G2714C on NM_012090.5) | Missense Mutation (SNP) | VAF 5/110 reads (5%) | catalogued as COSV57128141; called by muse, mutect2
- MAF | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58154699; called by muse, mutect2, varscan2
- MAGEB10 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV63311737; called by muse, mutect2, varscan2
- MAGI1 | c.1865A>G p.H622R | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as rs761508333, COSV58332513; called by muse, mutect2, varscan2
- MAGI2 | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1286180540, COSV62661068; called by muse, mutect2, varscan2
- MAMLD1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV53376275; called by muse, mutect2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 7/9 reads (78%) | catalogued as rs762648935; called by mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 80/244 reads (33%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MDH1B | c.1475A>T p.N492I | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV65590277; called by muse, mutect2
- ME3 | c.800T>A p.V267E | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV60165234; called by muse, mutect2
- MEGF8 | c.5840G>A p.G1947E (on ENST00000251268 / NM_001271938.2; = p.G1880E on NM_001410.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.585); catalogued as COSV52090032; called by muse, mutect2
- MLLT3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs1414201297, COSV63498633; called by muse, mutect2, varscan2
- MMP15 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143912189; called by muse, mutect2, varscan2
- MOCOS | c.2459C>A p.T820N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV54344759; called by muse, mutect2, varscan2
- MOGAT3 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs371428887; called by muse, mutect2, varscan2
- MPHOSPH6 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV50737045; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MRPL30 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs768048434, COSV57666840, COSV57667151; called by muse, mutect2, varscan2
- MRPS30 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50181773; called by muse, mutect2, varscan2
- MS4A8 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 5/113 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV55754828; called by muse, mutect2
- MSANTD4 | c.932G>T p.R311M | Missense Mutation (SNP) | VAF 29/455 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57286109; called by muse, mutect2
- MSMO1 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54970495; called by muse, mutect2
- MSX1 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM013013, COSV66947483; called by muse, mutect2, varscan2
- MTUS2 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1443904265, COSV70912573; called by muse, mutect2, varscan2
- MYH7B | c.241del p.E81Nfs*29 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as COSV53417111, COSV53421585; called by mutect2, varscan2
- MYO15A | c.3951C>A p.S1317R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52759399, COSV52761564; called by mutect2, varscan2
- MYO9A | c.6374A>G p.Y2125C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61853153; called by muse, mutect2
- NAA35 | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV64485269; called by muse, mutect2, varscan2
- NAV2 | c.1033G>A p.G345R (on ENST00000396087 / NM_001244963.2; = p.G322R on NM_145117.5) | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs142429988; called by muse, varscan2
- NDEL1 | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.864); catalogued as COSV55328350; called by muse, mutect2
- NDUFAF1 | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs766081384, COSV52975693; called by muse, mutect2, varscan2
- NFASC | c.1037T>C p.L346P (on ENST00000339876 / NM_001378329.1; = p.L357P on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58369212; called by muse, mutect2, varscan2
- NFKB1 | c.2776G>A p.D926N (on ENST00000394820 / NM_001382627.1; = p.D927N on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56957810; called by muse, mutect2, varscan2
- NINL | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs550403825, COSV54004357; called by muse, mutect2, varscan2
- NLRP14 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 115/298 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs139691301, COSV55064710; called by muse, mutect2, varscan2
- NMT1 | c.1382T>A p.F461Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV51960545; called by muse, mutect2, varscan2
- NOL9 | c.975T>A p.N325K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66626365; called by muse, mutect2, varscan2
- NOM1 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.107); catalogued as rs766181210, COSV51980646; called by muse, mutect2, varscan2
- NPR1 | c.1935G>T p.K645N | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64117745; called by muse, mutect2
- NRP2 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1225570944, COSV55930502; called by muse, mutect2, varscan2
- NRXN1 | c.1846G>T p.G616W | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58463836; called by muse, mutect2, varscan2
- NUDT10 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62854292; called by muse, mutect2, varscan2
- ONECUT1 | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59949539; called by muse, mutect2
- OR5L1 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV61734393; called by muse, mutect2
- PARP14 | c.2459T>C p.V820A | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71734927; called by muse, mutect2
- PCDHA13 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV56516192; called by muse, mutect2, varscan2
- PCDHGA8 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.323); catalogued as rs1281710551, COSV53972133; called by muse, mutect2, varscan2
- PCNT | c.6301G>A p.A2101T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV64029797; called by mutect2, varscan2
- PCYT1A | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53058151; called by muse, mutect2, varscan2
- PDZD2 | c.8399T>A p.I2800N | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56862217; called by muse, mutect2
- PGAP1 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.994); catalogued as COSV61327200; called by muse, mutect2, varscan2
- PHKA1 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59807447; called by muse, mutect2, varscan2
- PIGR | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 63/93 reads (68%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs201367607, COSV62904384; called by muse, mutect2, varscan2
- PIK3R1 | c.1924C>T p.R642* (on ENST00000521381 / NM_181523.3; = p.R372* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 52/188 reads (28%) | catalogued as rs1419325070, COSV57123056; called by muse, mutect2, varscan2
- PKD1L1 | c.7208_7209del p.S2403Yfs*5 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs755982540; called by pindel, varscan2
- PLA2G2C | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56124627; called by muse, mutect2
- PLA2G4D | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs779653077, COSV51819329; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100724507; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1642T>A p.Y548N | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs1400835293, COSV57966337; called by muse, mutect2
- POLG | c.1981C>G p.L661V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51522608; called by muse, mutect2, varscan2
- POLR1B | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs778970340, COSV54499875; called by muse, mutect2, varscan2
- PPFIA4 | c.3056G>A p.R1019Q (on ENST00000447715; = p.R1020Q on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV55312744, COSV55315903; called by muse, mutect2, varscan2
- PPP1R15A | c.1918_1929del p.P640_P643del | In Frame Del (DEL) | VAF 46/138 reads (33%) | catalogued as COSV52339440; called by mutect2, pindel, varscan2
- PPP1R3F | c.1051T>G p.F351V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV50018912; called by muse, mutect2, varscan2
- PPP2R5B | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51210756; called by muse, mutect2, varscan2
- PPP3R1 | c.395T>A p.I132N | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52247133; called by muse, mutect2
- PREX2 | c.1693dup p.S565Ffs*3 | Frame Shift Ins (INS) | VAF 22/108 reads (20%) | catalogued as rs764112302; called by mutect2, varscan2
- PTPRJ | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.21); catalogued as rs766468331, COSV69252936; called by muse, mutect2, varscan2
- PTPRU | c.3873C>A p.Y1291* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV60530317; called by muse, mutect2, varscan2
- RAB40AL | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 22/263 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.498); catalogued as COSV54433781, COSV54434839; called by muse, mutect2
- RANBP2 | c.2160G>T p.K720N | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV51703034; called by muse, mutect2
- RANBP6 | c.2578A>T p.T860S | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV52390095; called by muse, mutect2
- RAPGEF5 | c.659T>C p.L220P (on ENST00000401957 / NM_001367602.2; = p.L523P on NM_012294.5) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as COSV59785984; called by muse, mutect2
- RARS2 | c.340T>A p.L114I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.315); catalogued as COSV65761557; called by muse, mutect2
- RASGRF1 | c.3318G>T p.R1106S | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV60212800; called by muse, mutect2
- RBPMS | c.432C>A p.S144R | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV55124224; called by muse, mutect2, varscan2
- RCBTB2 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as COSV60650544; called by muse, varscan2
- RERE | c.102T>A p.N34K | Missense Mutation (SNP) | VAF 22/586 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV61944444; called by muse, mutect2
- RGS21 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV69882869; called by muse, mutect2
- RILPL2 | c.634T>C p.*212Qext*6 | Nonstop Mutation (SNP) | VAF 12/220 reads (5%) | catalogued as COSV54912721; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 38/72 reads (53%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPS6KA2 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55823000; called by muse, mutect2, varscan2
- RYR1 | c.2666G>A p.G889D | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62101270; called by muse, mutect2, varscan2
- RYR1 | c.9188C>T p.A3063V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.388); catalogued as COSV62101274; called by muse, mutect2, varscan2
- RYR3 | c.13006G>A p.E4336K (on ENST00000389232; = p.E4337K on NM_001036.6) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV66796090; called by muse, varscan2
- SALL4 | c.1173del p.F391Lfs*45 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as COSV53854337; called by mutect2, pindel, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 47/172 reads (27%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SEC14L1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs767606459, COSV66722028; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3B | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60351267; called by muse, mutect2, varscan2
- SEMG2 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 18/246 reads (7%) | catalogued as COSV65647607; called by muse, mutect2
- SERPIND1 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53139357; called by muse, mutect2
- SHLD2 | c.1472C>A p.T491N | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.697); catalogued as COSV53956289; called by muse, mutect2
- SIGLEC12 | c.1270C>T p.Q424* (on ENST00000291707 / NM_053003.4; = p.Q306* on NM_033329.2) | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV52462568, COSV99389522; called by muse, mutect2, varscan2
- SLC26A3 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as COSV60640964; called by muse, mutect2, varscan2
- SLC33A1 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs747418232, COSV63947296; called by muse, mutect2, varscan2
- SLC38A5 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58334649; called by muse, mutect2
- SLC39A7 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV63002671; called by muse, varscan2
- SLMAP | c.1243C>T p.P415S (on ENST00000428312 / NM_001377924.1; = p.P436S on NM_007159.5) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV55849348; called by muse, mutect2, varscan2
- SMC3 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs767014638, COSV62420744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMCO1 | c.645A>T p.*215Yext*5 | Nonstop Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV58838460; called by muse, mutect2, varscan2
- SMG1 | c.10442G>A p.R3481Q | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1201477844, COSV67172566; called by muse, mutect2, varscan2
- SMG1 | c.1423T>C p.C475R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.496); catalogued as COSV67172569; called by muse, mutect2, varscan2
- SNX25 | c.520T>A p.Y174N | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV53015708; called by muse, mutect2
- SNX7 | c.1051dup p.R351Kfs*14 | Frame Shift Ins (INS) | VAF 20/188 reads (11%) | catalogued as rs770251307; called by mutect2, pindel, varscan2
- SOCS4 | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV100215994, COSV59461010; called by muse, mutect2, varscan2
- SRF | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV54839112; called by muse, mutect2, varscan2
- SRFBP1 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 118/292 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as rs746226469, COSV59583352; called by muse, mutect2, varscan2
- SSTR1 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.74); catalogued as COSV57456606; called by muse, mutect2, varscan2
- ST18 | c.2849T>G p.L950R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52498243; called by muse, mutect2, varscan2
- STAT1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV61189749; called by muse, mutect2, varscan2
- STAU2 | c.1417A>T p.T473S (on ENST00000524300 / NM_001164380.2; = p.T441S on NM_014393.2) | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV63309036; called by muse, mutect2, varscan2
- STOX2 | c.2204T>A p.L735* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV57853449; called by muse, mutect2, varscan2
- SVEP1 | c.2933C>T p.S978L | Missense Mutation (SNP) | VAF 5/129 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57039705, COSV57041666; called by muse, mutect2
- SYBU | c.619A>T p.M207L (on ENST00000276646 / NM_001099754.2; = p.M206L on NM_017786.6) | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV52619902; called by muse, mutect2
- SYNE1 | c.3925C>T p.R1309* (on ENST00000367255 / NM_182961.4; = p.R1316* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV55017647; called by muse, mutect2
- SYNE2 | c.10228C>T p.L3410F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1389806410, COSV59955753; called by muse, mutect2, varscan2
- TAF1 | c.3137G>T p.C1046F (on ENST00000373790 / NM_138923.4; = p.C1067F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52116645; called by muse, mutect2, varscan2
- TAF1 | c.3288G>T p.Q1096H (on ENST00000373790 / NM_138923.4; = p.Q1117H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV52116661; called by muse, mutect2
- TAF13 | c.207T>G p.T69= | Splice Region (SNP) | VAF 66/157 reads (42%) | catalogued as COSV58040066; called by muse, mutect2, varscan2
- TANK | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52045800; called by muse, mutect2, varscan2
- TAP2 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 10/315 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV66499894; called by muse, mutect2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TCF12 | c.1807A>T p.M603L | Missense Mutation (SNP) | VAF 8/249 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV51010617; called by muse, mutect2
- TCOF1 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1562287919, COSV60350099; called by muse, mutect2
- TENM4 | c.8180A>G p.Q2727R | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53639821; called by muse, mutect2, varscan2
- TGFBR3 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 169/403 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148843052; called by muse, mutect2, varscan2
- TIGD2 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV57648160; called by muse, mutect2, varscan2
- TLN1 | c.2591C>T p.A864V | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59208787; called by muse, mutect2, varscan2
- TMEM144 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745556072, COSV56701610; called by muse, mutect2, varscan2
- TMTC2 | c.349T>A p.F117I | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV58273401; called by muse, mutect2
- TPPP2 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58795094; called by muse, mutect2
- TRIM27 | c.1505T>C p.V502A | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.246); catalogued as COSV65873710; called by muse, mutect2, varscan2
- TRMT2B | c.1368A>T p.E456D | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV58620009; called by muse, mutect2
- TRPC4AP | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.455); catalogued as COSV52681212; called by muse, mutect2
- TRPM4 | c.3161G>A p.S1054N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53264692; called by muse, mutect2, varscan2
- TSPAN12 | c.278T>A p.L93H | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56080357; called by muse, mutect2
- TTC29 | c.1017A>T p.K339N | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV57277189; called by muse, mutect2, varscan2
- TTF2 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV65632943; called by muse, mutect2, varscan2
- TTN | c.80110C>T p.P26704S (on ENST00000591111; = p.P19280S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/176 reads (5%) | PolyPhen probably damaging (0.998); catalogued as COSV60149936; called by muse, mutect2
- TTN | c.63144_63146del p.N21048del (on ENST00000591111; = p.N13624del on NM_003319.4) | In Frame Del (DEL) | VAF 9/93 reads (10%) | catalogued as rs774303656; called by pindel, varscan2
- TXNDC11 | c.599T>C p.M200T | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV51600309; called by muse, mutect2
- UGT2B11 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV71423556; called by muse, mutect2
- UQCRHL | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs774153442, COSV72331644; called by muse, mutect2, varscan2
- URI1 | c.231+1G>T p.X77_splice | Splice Site (SNP) | VAF 11/170 reads (6%) | catalogued as COSV56350950; called by muse, mutect2
- USP34 | c.2575G>T p.G859* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | catalogued as COSV68402753; called by muse, mutect2
- USP44 | c.1808A>G p.Y603C | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51562247; called by muse, mutect2, varscan2
- VMA21 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57756912; called by muse, mutect2, varscan2
- WBP4 | c.1127A>G p.Q376R | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV65274139; called by muse, mutect2
- WDR62 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54336255; called by muse, mutect2, varscan2
- WNK4 | c.2147C>T p.A716V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55906404; called by muse, mutect2, varscan2
- XKR7 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs187823882, COSV73813160; called by muse, mutect2, varscan2
- ZBED1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1170638506, COSV58130147; called by muse, mutect2, varscan2
- ZBTB7C | c.403del p.E135Rfs*87 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs747456682, COSV59688820; called by mutect2, pindel, varscan2
- ZC3H6 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs367887186; called by muse, mutect2, varscan2
- ZCCHC3 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV66643430; called by muse, varscan2
- ZFP28 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.158); catalogued as rs774345162, COSV56736508; called by muse, mutect2
- ZFYVE1 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59611639; called by muse, mutect2
- ZHX2 | c.950A>G p.H317R | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV58714301; called by muse, mutect2
- ZKSCAN2 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs764792410, COSV60157479; called by muse, mutect2, varscan2
- ZNF275 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64704791; called by muse, mutect2, varscan2
- ZNF382 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53089380, COSV53091347; called by muse, mutect2
- ZNF479 | c.381del p.K127Nfs*74 | Frame Shift Del (DEL) | VAF 80/236 reads (34%) | catalogued as rs782331095; called by mutect2, varscan2
- ZNF638 | c.3912del p.G1305Vfs*22 | Frame Shift Del (DEL) | VAF 37/129 reads (29%) | catalogued as rs1196097264; called by mutect2, varscan2
- ZNF792 | c.1186T>C p.C396R | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68693187; called by muse, mutect2
- ZNF862 | c.2048T>C p.I683T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV56224499; called by muse, mutect2, varscan2
- ZP1 | c.1181del p.P394Hfs*6 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as COSV53925991; called by mutect2, pindel, varscan2
- ZSWIM2 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV54575714, COSV54576543; called by muse, mutect2
- ZXDC | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as rs1402269135, COSV60447477; called by muse, mutect2, varscan2
- ACACA | c.5493del p.E1832Rfs*8 | Frame Shift Del (DEL) | VAF 38/135 reads (28%) | called by mutect2, pindel, varscan2
- ALDH18A1 | c.827del p.P276Qfs*20 | Frame Shift Del (DEL) | VAF 14/152 reads (9%) | called by mutect2, pindel
- ALDH18A1 | c.169_170del p.H57Wfs*9 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | called by pindel, varscan2
- ALKBH6 | c.72_74del p.Y25del (on ENST00000252984 / NM_001297701.2; = p.Y53del on NM_032878.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 26/76 reads (34%) | called by pindel, varscan2
- AMY2B | c.665_666del p.I222Kfs*9 | Frame Shift Del (DEL) | VAF 220/970 reads (23%) | called by mutect2, varscan2
- ASPM | c.122_123del p.L41Qfs*30 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by pindel, varscan2
- ATP6V0A2 | c.362del p.N121Tfs*5 | Frame Shift Del (DEL) | VAF 97/343 reads (28%) | called by mutect2, pindel, varscan2
- C12orf29 | c.923del p.L308* | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 15/126 reads (12%) | called by mutect2, pindel
- CLASP1 | c.4442_4447dup p.K1482_A1483insGK | In Frame Ins (INS) | VAF 8/19 reads (42%) | called by mutect2, varscan2
- CNDP2 | c.1314del p.S439Qfs*19 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- ELAPOR2 | c.2909_2910del p.K970Rfs*3 (on ENST00000450689 / NM_001142749.3; = p.K803Rfs*3 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- EPHA4 | c.733del p.M245Cfs*89 | Frame Shift Del (DEL) | VAF 13/142 reads (9%) | called by mutect2, pindel
- GGNBP2 | c.2074A>T p.T692S | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); called by muse, mutect2
- GRK4 | c.505del p.S169Lfs*14 (on ENST00000398052 / NM_182982.3; = p.S137Lfs*14 on NM_005307.3) | Frame Shift Del (DEL) | VAF 37/105 reads (35%) | called by mutect2, pindel, varscan2
- IGHV3-21 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 26/544 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); called by muse, mutect2
- IGKV1D-17 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 121/383 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- INPPL1 | c.1590dup p.K531Efs*21 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by pindel, varscan2
- KCNH1 | c.2480del p.G827Afs*48 (on ENST00000271751 / NM_172362.3; = p.G800Afs*48 on NM_002238.4) | Frame Shift Del (DEL) | VAF 23/108 reads (21%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.4576del p.L1526Wfs*13 | Frame Shift Del (DEL) | VAF 94/266 reads (35%) | called by mutect2, pindel, varscan2
- KMT2C | c.1955del p.N652Tfs*19 | Frame Shift Del (DEL) | VAF 74/249 reads (30%) | called by mutect2, pindel, varscan2
- LGR4 | c.2467del p.S823Vfs*33 | Frame Shift Del (DEL) | VAF 19/226 reads (8%) | called by mutect2, pindel
- LVRN | c.1694del p.N565Tfs*2 | Frame Shift Del (DEL) | VAF 22/160 reads (14%) | called by mutect2, varscan2
- OR8H1 | c.530del p.F177Sfs*8 | Frame Shift Del (DEL) | VAF 43/163 reads (26%) | called by mutect2, pindel, varscan2
- PADI2 | c.1247dup p.V417Sfs*33 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- PCDHA4 | c.629del p.L210* | Frame Shift Del (DEL) | VAF 9/100 reads (9%) | called by mutect2, pindel
- POSTN | c.1670del p.N557Mfs*11 | Frame Shift Del (DEL) | VAF 54/145 reads (37%) | called by mutect2, pindel, varscan2
- PPP1R9A | c.267del p.G91Vfs*10 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- SAR1B | c.263del p.N88Tfs*22 | Frame Shift Del (DEL) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- SHROOM2 | c.953del p.P318Lfs*143 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- SOS1 | c.3090del p.K1030Nfs*6 | Frame Shift Del (DEL) | VAF 18/156 reads (12%) | called by mutect2, pindel, varscan2
- SPOP | c.675del p.F225Lfs*30 | Frame Shift Del (DEL) | VAF 29/263 reads (11%) | called by mutect2, pindel, varscan2
- ST8SIA3 | c.338dup p.N113Kfs*8 | Frame Shift Ins (INS) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- TNRC6B | c.1124del p.N375Mfs*7 | Frame Shift Del (DEL) | VAF 62/193 reads (32%) | called by mutect2, varscan2
- TTK | c.575del p.K192Sfs*18 | Frame Shift Del (DEL) | VAF 14/145 reads (10%) | called by mutect2, pindel, varscan2
- TTPA | c.652dup p.I218Nfs*2 | Frame Shift Ins (INS) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- UBTD1 | c.417del p.E140Sfs*12 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- XCL1 | c.201dup p.V68Sfs*4 | Frame Shift Ins (INS) | VAF 23/184 reads (13%) | called by mutect2, varscan2
- XYLT1 | c.2169dup p.V724Sfs*10 | Frame Shift Ins (INS) | VAF 24/268 reads (9%) | called by mutect2, pindel
- XYLT2 | c.1586del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- ZBED4 | c.948del p.K317Rfs*61 | Frame Shift Del (DEL) | VAF 10/103 reads (10%) | called by mutect2, pindel
- ZNF26 | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF609 | c.2341del p.H781Tfs*42 | Frame Shift Del (DEL) | VAF 20/187 reads (11%) | called by mutect2, pindel, varscan2
- ADAM22 | c.765T>C p.H255= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV55980682; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1143T>C p.P381= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1349894068, COSV55001741; called by muse, mutect2, varscan2
- AKAP14 | c.579A>G p.L193= | Silent (SNP) | VAF 44/123 reads (36%) | catalogued as COSV57630534; called by muse, mutect2, varscan2
- AKAP4 | c.1140C>T p.S380= | Silent (SNP) | VAF 71/185 reads (38%) | catalogued as rs140947270, COSV62074614; called by muse, mutect2, varscan2
- AL121899.2 | c.369C>T p.A123= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as COSV67351146; called by muse, mutect2, varscan2
- AMER1 | c.771T>C p.D257= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as COSV57662495; called by muse, mutect2
- CATSPER3 | c.276C>T p.S92= | Silent (SNP) | VAF 8/183 reads (4%) | catalogued as COSV50945234; called by muse, mutect2
- CD37 | c.777C>T p.F259= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV60544695; called by muse, mutect2, varscan2
- CDC42EP4 | c.471G>A p.A157= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs748235240, COSV59963262; called by muse, mutect2, varscan2
- CEACAM18 | c.234G>A p.P78= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs762385365, COSV67283316; called by muse, mutect2, varscan2
- COL4A1 | c.1110C>T p.P370= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as rs368143409; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL4A6 | c.3873C>T p.T1291= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs771062602, COSV57869741; called by muse, mutect2, varscan2
- CRB1 | c.1692T>C p.D564= | Silent (SNP) | VAF 32/594 reads (5%) | catalogued as rs769929726, COSV66331269; called by muse, mutect2
- CSHL1 | c.310T>C p.L104= (on ENST00000309894 / NM_022581.3; = p.L10= on NM_001318.4) | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs539771280, COSV51988770; called by muse, mutect2, varscan2
- DDX55 | c.561C>T p.T187= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV53016516; called by muse, mutect2, varscan2
- DIAPH2 | c.1776A>C p.P592= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs773914991, COSV61275208; called by muse, mutect2, varscan2
- DNAH3 | c.11877G>C p.G3959= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV54530191; called by muse, mutect2, varscan2
- DSG1 | c.1464T>C p.N488= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as rs1194136702, COSV57136751; called by muse, mutect2
- DUOXA1 | c.186C>T p.F62= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV50993910; called by muse, mutect2, varscan2
- EIF4G2 | c.135A>G p.Q45= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV60597909; called by muse, mutect2
- ERC2 | c.2421T>C p.N807= | Silent (SNP) | VAF 26/286 reads (9%) | catalogued as rs764048315, COSV55633492; called by muse, mutect2
- EXOC2 | c.2686C>T p.L896= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV57867297; called by muse, mutect2
- FGD2 | c.1851G>A p.Q617= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV51464331; called by muse, mutect2, varscan2
- FIP1L1 | c.1107T>C p.L369= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV60997540; called by muse, mutect2, varscan2
- FRMD4A | c.144T>C p.L48= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52727289; called by muse, mutect2, varscan2
- GALNT5 | c.1047A>G p.K349= | Silent (SNP) | VAF 22/264 reads (8%) | catalogued as COSV52038764; called by muse, mutect2
- GDPD4 | c.561C>T p.C187= | Silent (SNP) | VAF 13/275 reads (5%) | catalogued as COSV60019912, COSV60020336; called by muse, mutect2
- GLUD2 | c.240C>T p.I80= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs751308697, COSV60152105; called by muse, mutect2, varscan2
- GPR179 | c.6231C>A p.P2077= (on ENST00000621958; = p.P2076= on NM_001004334.4) | Silent (SNP) | VAF 24/181 reads (13%) | called by muse, mutect2, varscan2
- HNRNPA3 | c.765C>T p.G255= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV66820934; called by muse, mutect2
- HOXA3 | c.582G>A p.A194= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV57827237; called by muse, mutect2, varscan2
- IFNGR2 | c.249G>A p.G83= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs141609920; ClinVar: likely benign; called by muse, mutect2, varscan2
- IL11RA | c.615A>G p.T205= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV52405218; called by muse, mutect2, varscan2
- JARID2 | c.2856T>C p.I952= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV59191536; called by muse, mutect2, varscan2
- KIAA0319 | c.396C>T p.D132= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV65499568; called by mutect2, varscan2
- KIF24 | c.345G>C p.G115= | Silent (SNP) | VAF 11/121 reads (9%) | catalogued as COSV61456179; called by muse, mutect2
- MEX3C | c.1866A>G p.P622= | Silent (SNP) | VAF 85/219 reads (39%) | catalogued as COSV68530154; called by muse, mutect2, varscan2
- MRPL37 | c.453C>T p.D151= | Silent (SNP) | VAF 21/262 reads (8%) | catalogued as rs755862505, COSV60322058; called by muse, mutect2
- MYBPC2 | c.1824G>A p.A608= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs373184181, COSV63093208; called by mutect2, varscan2
- MYOM2 | c.3918C>T p.F1306= | Silent (SNP) | VAF 74/152 reads (49%) | catalogued as rs369265146; called by muse, mutect2, varscan2
- NPAT | c.3663T>C p.L1221= | Silent (SNP) | VAF 14/354 reads (4%) | catalogued as COSV53718996; called by muse, mutect2
- NR2F1 | c.549C>T p.C183= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1479824500, COSV59069139; called by muse, mutect2, varscan2
- NXF1 | c.1746C>T p.L582= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs181325349, COSV53674665; called by muse, mutect2, varscan2
- NXT1 | c.90G>A p.K30= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV54783112; called by muse, mutect2
- OCRL | c.1284C>T p.C428= | Silent (SNP) | VAF 23/468 reads (5%) | catalogued as COSV63981163; called by muse, mutect2
- OPN3 | c.537C>T p.Y179= | Silent (SNP) | VAF 24/249 reads (10%) | catalogued as COSV59365301; called by muse, mutect2
- PAM | c.1836C>T p.G612= | Silent (SNP) | VAF 26/193 reads (13%) | catalogued as COSV57215171; called by muse, mutect2, varscan2
- PCDHB7 | c.1494G>T p.L498= | Silent (SNP) | VAF 59/115 reads (51%) | catalogued as COSV50781161; called by muse, mutect2, varscan2
- PDK4 | c.172C>A p.R58= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV50011390; called by muse, mutect2, varscan2
- PHACTR2 | c.1590A>G p.L530= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV59855674; called by muse, mutect2
- PLXNB1 | c.3465C>T p.H1155= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs751648829, COSV56490712; called by muse, mutect2
- PRR5-ARHGAP8 | c.1038C>A p.V346= (on ENST00000352766; = p.V267= on NM_181334.5) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV61234658; called by muse, mutect2, varscan2
- PSMB6 | c.390G>A p.A130= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as rs746269217, COSV54513107; called by muse, mutect2, varscan2
- PSMD7 | c.705C>T p.N235= | Silent (SNP) | VAF 4/86 reads (5%) | catalogued as COSV54697908; called by muse, mutect2
- PTK7 | c.564G>A p.R188= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV57849461; called by mutect2, varscan2
- RALBP1 | c.1086A>G p.T362= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs746115345, COSV50036200; called by muse, mutect2, varscan2
- ROCK2 | c.2823A>G p.K941= | Silent (SNP) | VAF 36/331 reads (11%) | catalogued as COSV59955452, COSV59959662; called by muse, mutect2, varscan2
- SCN2A | c.5334C>T p.N1778= | Silent (SNP) | VAF 133/631 reads (21%) | catalogued as COSV51845931; called by muse, mutect2, varscan2
- SEPTIN9 | c.378C>A p.G126= (on ENST00000427177 / NM_001113491.2; = p.G108= on NM_006640.4) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV61206803; called by muse, mutect2
- SP140 | c.651A>G p.L217= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV59451273; called by muse, mutect2
- SRP68 | c.1227G>A p.Q409= | Silent (SNP) | VAF 4/79 reads (5%) | catalogued as COSV57162718; called by muse, mutect2
- STK4 | c.729A>G p.T243= | Silent (SNP) | VAF 16/260 reads (6%) | catalogued as COSV65670600; called by muse, mutect2
- SUCO | c.2523C>A p.A841= | Silent (SNP) | VAF 28/406 reads (7%) | catalogued as COSV55267033; called by muse, mutect2
- TCHH | c.4147C>T p.L1383= | Silent (SNP) | VAF 20/652 reads (3%) | catalogued as COSV64275684; called by muse, mutect2
- THNSL1 | c.624C>A p.S208= | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as COSV64479489; called by muse, mutect2
- TLK2 | c.1053T>A p.G351= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as COSV58301900; called by muse, mutect2
- TMEM255A | c.387T>C p.H129= | Silent (SNP) | VAF 14/310 reads (5%) | catalogued as COSV59029964; called by muse, mutect2
- TRIM74 | c.555G>A p.P185= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs565770046, COSV53533087; called by mutect2, varscan2
- TTBK2 | c.588C>T p.N196= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs531094726, COSV51158327; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTC7B | c.1719C>T p.D573= | Silent (SNP) | VAF 28/262 reads (11%) | catalogued as COSV60633647, COSV60640985; called by muse, mutect2
- UBAP2L | c.2088G>A p.T696= | Silent (SNP) | VAF 46/283 reads (16%) | catalogued as rs1366202075, COSV55175606; called by muse, mutect2, varscan2
- UBR4 | c.6471C>T p.G2157= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV64389161, COSV64392326; called by muse, mutect2
- UGP2 | c.666T>C p.G222= | Silent (SNP) | VAF 12/389 reads (3%) | catalogued as COSV61428672; called by muse, mutect2
- USP14 | c.1203T>C p.Y401= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV55275909; called by muse, mutect2
- VNN1 | c.918C>A p.S306= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV63390142; called by muse, mutect2, varscan2
- ZAN | c.4152T>C p.D1384= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1238090175, COSV61810754; called by muse, mutect2
- ZFP69 | c.84G>C p.G28= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV65529197; called by muse, mutect2, varscan2
- ZKSCAN8 | c.24T>G p.P8= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV57638980; called by muse, mutect2, varscan2
- ZNF367 | c.765G>A p.E255= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as rs1436289974, COSV64547224; called by muse, mutect2, varscan2
- ZNF536 | c.2742C>T p.F914= | Silent (SNP) | VAF 68/175 reads (39%) | catalogued as rs781726692, COSV62822080; called by muse, mutect2, varscan2
- BRD9 | c.401-15del | Intron (DEL) | VAF 12/46 reads (26%) | catalogued as rs747777302, COSV51319227; called by mutect2, varscan2
- EIF4A2 | c.909+45T>A | Intron (SNP) | VAF 7/158 reads (4%) | called by muse, mutect2
- KIF1B | c.2115+6888T>C | Intron (SNP) | VAF 17/512 reads (3%) | catalogued as COSV99824050; called by muse, mutect2
- OR3A4P | n.1096G>A | RNA (SNP) | VAF 77/194 reads (40%) | catalogued as rs558430652; called by muse, mutect2, varscan2
- PTPRM | c.2527+239G>T | Intron (SNP) | VAF 23/481 reads (5%) | catalogued as COSV100159830; called by muse, mutect2
- PVRIG | chr7:100223904 G>A | 3'Flank (SNP) | VAF 5/53 reads (9%) | catalogued as rs1408246132, COSV52781669; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18551A>T | Intron (SNP) | VAF 6/61 reads (10%) | catalogued as COSV67445642; called by muse, mutect2
- STK4 | c.1306-21929del | Intron (DEL) | VAF 16/131 reads (12%) | called by mutect2, pindel, varscan2
- TCF7L2 | c.552+49327del | Intron (DEL) | VAF 14/54 reads (26%) | catalogued as rs756433967; called by mutect2, pindel, varscan2
- TOR1AIP2 | c.-146-12196C>A | Intron (SNP) | VAF 170/703 reads (24%) | catalogued as COSV100857515; called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28579872 A>C | 3'Flank (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- WNK1 | c.2140-2230C>A | Intron (SNP) | VAF 35/562 reads (6%) | catalogued as COSV60037015; called by muse, mutect2
